TCGA case TCGA-QR-A70P — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Retroperitoneum and peritoneum; Tissue source site: National Institutes of Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a39ac229-60d2-42c2-9721-7e0894c0ae38

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Dead; Days to death: 3,563 days (9.8 years).

Diagnoses (3)
1. Extra-adrenal paraganglioma, NOS (the primary disease): ICD-O-3 morphology code: 8693/1; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 45.6 years (16,655 days); Year of diagnosis: 2004; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 704 days (1.9 years); Days to treatment end: 704 days (1.9 years); Treatment outcome: Progressive Disease; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dacarbazine + Vincristine; Days to treatment start: 966 days (2.6 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 2,963 days (8.1 years); Treatment dose: 2,000 cGy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Distant Site.
2. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Head, face or neck, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 45.0 years (16,420 days); Days to diagnosis: -235 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -174 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Extra-adrenal paraganglioma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 47.4 years (17,303 days); Days to diagnosis: 648 days (1.8 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Day 648 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to recurrence: 648 days (1.8 years).
- Days to follow up: 3,563 days (9.8 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QR-A70P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-QR-A70P-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QR-A70P-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QR-A70P-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: L glomus tumor; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Histologic diagnosis: Paraganglioma; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- Drug treatment: Pharmaceutical therapy drug name: cyclophosphamide, vincristine, and dacarbazine; Clinical trial drug classification: CVD; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Head/Neck; Other malignancy histological type: paraganglioma.
- Other malignancy form, Surgery: Other malignancy surgery type: resection of paraganglioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,563 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 3,563 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 648 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QR-A70P-01A-11D-A35C-01): tumor purity 0.81, ploidy 1.94, whole-genome doublings 0.
